Somatic mutation profile of tumor specimen ALCH-ABV5-TTP1-A (aliquot ALCH-ABV5-TTP1-A-1-0-D-A490-36) from ALCHEMIST case ALCH-ABV5, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.8 years (22,197 days).
Specimen ALCH-ABV5-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d7a4d35-4068-48b0-875f-0bb395125a8d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ABV5-NB1-A (Blood Derived Normal), aliquot ALCH-ABV5-NB1-A-1-0-D-A490-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/637b7b89-7e3a-4813-b198-5b2fb61828df

The open-access MAF lists 29 somatic variants for this specimen: 21 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 7, Nonsense Mutation 2, Splice Site 2, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 106/652 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- EXOC3 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 76/771 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.2); catalogued as rs1457115309, COSV59266200; called by muse, mutect2
- GPR107 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 38/258 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs772249004, COSV61280503; called by muse, mutect2, varscan2
- SLC22A24 | c.1623G>T p.K541N | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.085); catalogued as rs1207661470; called by muse, mutect2, varscan2
- SLC6A19 | c.587G>A p.W196* | Nonsense Mutation (SNP) | VAF 40/812 reads (5%) | catalogued as rs138326359; called by muse, mutect2
- SUGT1P4-STRA6LP | n.1035+5G>A | Splice Region (SNP) | VAF 17/119 reads (14%) | catalogued as rs768035536; called by muse, mutect2, varscan2
- AHRR | c.1928C>T p.S643F | Missense Mutation (SNP) | VAF 104/514 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- ANKRD17 | c.6928C>A p.P2310T | Missense Mutation (SNP) | VAF 14/454 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.098); called by muse, mutect2
- EXOC3 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 156/1064 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.38); called by muse, varscan2
- FOXR1 | c.625T>C p.F209L | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- KNL1 | c.3614C>T p.T1205I (on ENST00000346991 / NM_170589.5; = p.T1179I on NM_144508.5) | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PCDHGC5 | c.899G>T p.G300V | Missense Mutation (SNP) | VAF 22/396 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- POP7 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 13/359 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.285); called by muse, mutect2
- PPP1R21 | c.517C>T p.Q173* | Nonsense Mutation (SNP) | VAF 29/122 reads (24%) | called by muse, mutect2, varscan2
- RBM10 | c.1950+1G>T p.X650_splice | Splice Site (SNP) | VAF 60/363 reads (17%) | called by muse, mutect2, varscan2
- REC8 | c.1451+3_1451+29del p.X484_splice | Splice Site (DEL) | VAF 24/166 reads (14%) | called by mutect2, pindel
- RPRD2 | c.3656C>T p.P1219L | Missense Mutation (SNP) | VAF 9/230 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2
- SNX17 | c.1298C>T p.S433L | Missense Mutation (SNP) | VAF 44/308 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- SUN5 | c.578A>G p.Y193C | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.87); called by muse, mutect2
- TBXA2R | c.143T>A p.V48E | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- TRPV3 | c.2104G>C p.E702Q | Missense Mutation (SNP) | VAF 11/199 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.276); called by muse, mutect2
- ADGRE1 | c.2064G>C p.V688= | Silent (SNP) | VAF 76/370 reads (21%) | catalogued as COSV51675527, COSV51677427; called by muse, mutect2, varscan2
- CCDC7 | c.3411C>T p.I1137= | Silent (SNP) | VAF 7/149 reads (5%) | called by muse, mutect2
- HIP1 | c.996C>T p.L332= | Silent (SNP) | VAF 30/138 reads (22%) | catalogued as rs1563205025, COSV61183419; called by muse, mutect2, varscan2
- MAST1 | c.2824C>T p.L942= | Silent (SNP) | VAF 20/252 reads (8%) | called by muse, mutect2
- NRROS | c.348C>T p.C116= | Silent (SNP) | VAF 20/120 reads (17%) | catalogued as rs1452668609; called by muse, mutect2, varscan2
- OTUD7A | c.2067T>C p.A689= (on ENST00000307050 / NM_001382637.1; = p.A682= on NM_130901.3) | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs1398694572, COSV61036567; called by mutect2, varscan2
- TMEM63C | c.1173C>A p.P391= | Silent (SNP) | VAF 22/196 reads (11%) | catalogued as COSV53606054; called by muse, mutect2, varscan2
- BSCL2 | chr11:62709333 G>C | 5'Flank (SNP) | VAF 75/433 reads (17%) | called by muse, mutect2, varscan2
